Somatic mutation profile of tumor specimen TCGA-D8-A1Y0-01A (aliquot TCGA-D8-A1Y0-01A-11D-A14K-09) from TCGA case TCGA-D8-A1Y0, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 65.9 years (24,083 days).
Specimen TCGA-D8-A1Y0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca2cc5b7-4402-44c6-be4c-2a20bd507461.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D8-A1Y0-10A (Blood Derived Normal), aliquot TCGA-D8-A1Y0-10A-01D-A14K-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a2d2fe6-5884-4356-b27d-b8d561f6212f

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 17, In Frame Del 2, Nonsense Mutation 2, Intron 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK5 | c.724A>C p.I242L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.03); catalogued as COSV100450482; called by muse, mutect2
- ADH5 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV56448831; called by muse, mutect2
- ARID5B | c.652A>T p.R218W | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.445); catalogued as COSV54427809; called by muse, mutect2, varscan2
- BRD3 | c.715-1G>A p.X239_splice | Splice Site (SNP) | VAF 9/42 reads (21%) | catalogued as rs1186231882, COSV100325139; called by muse, mutect2
- CEP250 | c.5019G>T p.Q1673H | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.54); PolyPhen benign (0.346); catalogued as COSV61173481; called by muse, mutect2, varscan2
- DMBT1 | c.2392G>T p.D798Y | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100352504, COSV100353139; called by muse, mutect2
- ELL2 | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as rs979816138, COSV52984627; called by muse, mutect2, varscan2
- FCHO1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs1478477343, COSV53184659; called by muse, mutect2, varscan2
- GFPT1 | c.1161G>C p.L387F (on ENST00000357308 / NM_001244710.2; = p.L369F on NM_002056.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV61950030; called by muse, mutect2, varscan2
- GSDMC | c.945T>C p.N315= | Splice Region (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99416057; called by muse, mutect2
- GSTM4 | c.471T>G p.D157E | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100264326, COSV58695926; called by muse, mutect2, varscan2
- GSTM4 | c.472T>A p.F158I | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV58695952; called by muse, mutect2, varscan2
- HEATR5A | c.3740A>T p.H1247L | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66344505; called by muse, mutect2, varscan2
- HIVEP3 | c.797A>G p.E266G | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.057); catalogued as rs1201591282, COSV56021661; called by muse, mutect2, varscan2
- KXD1 | c.484A>T p.I162F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.048); catalogued as COSV55890359; called by muse, mutect2, varscan2
- LRIG2 | c.161T>A p.L54Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV63163709; called by muse, mutect2, varscan2
- MAP6 | c.2137G>A p.V713M | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.017); catalogued as rs778895817, COSV59077206; called by muse, mutect2, varscan2
- MTOR | c.6302G>T p.W2101L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63876881; called by muse, mutect2, varscan2
- MYH8 | c.4691T>A p.I1564N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV67970843; called by muse, mutect2, varscan2
- NDUFV1 | c.552G>C p.K184N | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV59596343; called by muse, mutect2, varscan2
- NINL | c.873G>C p.E291D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs776628214, COSV54007483; called by muse, mutect2, varscan2
- NOMO2 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57917911; called by muse, mutect2, varscan2
- NUP210 | c.4738G>A p.A1580T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54412217; called by muse, mutect2, varscan2
- PCDHA9 | c.2265G>T p.R755S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV65331531; called by muse, mutect2, varscan2
- PCDHB11 | c.1532G>C p.G511A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61313609, COSV61313937; called by muse, mutect2, varscan2
- PCNX3 | c.418G>C p.V140L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV58421336; called by muse, mutect2, varscan2
- PLCL1 | c.2657T>A p.I886N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.171); catalogued as COSV101406784, COSV70864990; called by muse, mutect2, varscan2
- PLEC | c.2344A>G p.S782G (on ENST00000322810 / NM_201380.4; = p.S672G on NM_000445.5) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59681901; called by muse, mutect2, varscan2
- POMGNT2 | c.1390G>C p.V464L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV100768086; called by muse, mutect2, varscan2
- PPL | c.1774G>A p.D592N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs1314909854, COSV100630828; called by muse, mutect2
- RAD51C | c.954C>A p.D318E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV61677025; called by muse, mutect2, varscan2
- SBNO1 | c.3212T>A p.F1071Y (on ENST00000420886; = p.F1070Y on NM_018183.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57344912; called by muse, mutect2, varscan2
- SLC1A3 | c.55C>T p.Q19* | Nonsense Mutation (SNP) | VAF 10/51 reads (20%) | catalogued as COSV54314420; called by muse, mutect2, varscan2
- SNAPC1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as COSV53520955; called by mutect2, varscan2
- SORBS2 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53011976; called by muse, mutect2, varscan2
- SOS2 | c.2864A>G p.N955S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.84); catalogued as COSV53572842; called by muse, mutect2, varscan2
- SPATA18 | c.1502G>T p.S501I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV54649023; called by muse, mutect2, varscan2
- THAP12 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as rs775717873, COSV52610143; called by muse, mutect2, varscan2
- TNRC18 | c.8634C>A p.D2878E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV99786821; called by muse, mutect2
- TPST1 | c.896T>C p.L299P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100507147; called by muse, mutect2, varscan2
- UBE4B | c.569A>G p.N190S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.138); catalogued as COSV53540216; called by muse, mutect2, varscan2
- USP53 | c.2780A>T p.K927M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56797057; called by muse, mutect2, varscan2
- ZNF518B | c.1913C>G p.S638C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58724379; called by muse, mutect2, varscan2
- ZNF555 | c.791C>G p.A264G | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV62073827; called by muse, mutect2, varscan2
- ZNF619 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as COSV59030949; called by muse, mutect2, varscan2
- ARSK | c.813_828del p.I272Hfs*24 | Frame Shift Del (DEL) | VAF 20/57 reads (35%) | called by mutect2, pindel, varscan2
- C2CD3 | c.5327_5335del p.Q1776_R1778del | In Frame Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- MASP2 | c.966_989del p.S323_T330del | In Frame Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- ZNF658 | c.347A>C p.Q116P | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by mutect2, varscan2
- ABCG1 | c.84G>A p.S28= | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as rs751989691, COSV59209237; called by muse, mutect2, varscan2
- ADAMTS20 | c.2301C>T p.D767= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs550143996, COSV67137561; called by muse, mutect2, varscan2
- ADARB2 | c.1428A>G p.R476= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV67233832; called by muse, mutect2, varscan2
- ATP1A3 | c.243C>T p.N81= (on ENST00000545399 / NM_001256214.2; = p.N68= on NM_152296.5) | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs148043407; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNA1E | c.1305C>A p.I435= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100702320, COSV62413258; called by muse, mutect2, varscan2
- ERN2 | c.1491C>A p.P497= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99891643; called by muse, mutect2, varscan2
- FGF3 | c.510C>T p.R170= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV61926702; called by muse, mutect2, varscan2
- IKZF3 | c.789G>T p.V263= | Silent (SNP) | VAF 8/125 reads (6%) | catalogued as COSV99499720; called by muse, mutect2
- KCNB2 | c.765A>G p.S255= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV73052379; called by muse, mutect2, varscan2
- KIF26B | c.4860C>T p.G1620= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs756415434, COSV63649277; called by muse, mutect2
- MTF2 | c.1635C>G p.L545= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV64771922; called by muse, mutect2, varscan2
- NOP2 | c.2331C>G p.P777= (on ENST00000322166 / NM_001258308.2; = p.P773= on NM_006170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV59113000; called by muse, mutect2, varscan2
- OTOF | c.459C>T p.L153= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV55515470; called by muse, mutect2, varscan2
- PSMA7 | c.297G>A p.E99= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs1312188119, COSV53382811; called by muse, mutect2, varscan2
- PTGIR | c.1050G>T p.S350= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99354988; called by muse, mutect2, varscan2
- SEC24A | c.390C>A p.A130= | Silent (SNP) | VAF 30/79 reads (38%) | catalogued as COSV59749291; called by muse, mutect2, varscan2
- TBC1D2 | c.624C>G p.L208= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV59787990; called by muse, mutect2, varscan2
- AOPEP | c.*5-659C>T | Intron (SNP) | VAF 12/33 reads (36%) | catalogued as COSV52997257; called by muse, mutect2, varscan2
- RHOT1 | c.1739+1096G>C | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as COSV61717920; called by muse, mutect2, varscan2
